Somatic mutation profile of tumor specimen TCGA-AB-2954-03A (aliquot TCGA-AB-2954-03A-01W-0733-08) from TCGA case TCGA-AB-2954, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myelomonocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 55.3 years (20,211 days).
Specimen TCGA-AB-2954-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcd30fd9-61eb-4e80-835f-5a3831cb2bbe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2954-11A (Solid Tissue Normal), aliquot TCGA-AB-2954-11A-01W-0732-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/686e29d3-fdd6-45c2-92b8-132858b3c442

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARHGAP6 | c.960T>A p.N320K | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.07); catalogued as COSV100272950; called by muse, mutect2
